Gene-level copy-number profile of tumor specimen TCGA-WE-A8JZ-06A from TCGA case TCGA-WE-A8JZ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.9 years (26,255 days).
Specimen TCGA-WE-A8JZ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.249aafd5-6d39-44e9-8ca0-e597ee3928e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WE-A8JZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/94d5d511-5cd1-435a-845c-a2a4e6664de1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 128; copy number 2: 19,550; copy number 3: 9,475; copy number 4: 25,722; copy number 5: 3,529; copy number 6: 330; copy number 8: 108; copy number 9: 960.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WE-A8JZ-06A-11D-A371-01): tumor purity 0.84, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,128,103, 16 genes (within-gene range 0–2): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 960 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:88,061,774–89,065,945, 12 genes, copy number 9 (within-gene range 2–9): AP005436.1, AP005436.2, Y_RNA, RAB38, AP001642.1, MIR3166, CTSC, GAPDHP70, AP003120.1, GRM5-AS1, GRM5, RNU6-16P.
- chr20:25,294,742–64,313,132, 948 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 128. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
